TCGA case TCGA-B6-A0I8 — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6e6408d6-6c48-4dfc-9f1c-28b7386e87b4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 46 years; Vital status: Dead; Days to death: 749 days (2.1 years).

Diagnoses (3)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 46.7 years (17,073 days); Year of diagnosis: 1992; Method of diagnosis: Biopsy; AJCC staging edition: 4th; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage X; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Inner / Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes tested: 0; Micrometastasis present: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Breast, NOS; Laterality: Left; Classification of tumor: Prior primary; AJCC staging edition: 2nd; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Connective, subcutaneous and other soft tissues of thorax. Age at diagnosis: 48.8 years (17,819 days); Days to diagnosis: 746 days (2.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Treatment anatomic sites: Locoregional Site.

Follow-up (2 entries)
- Day 746 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of thorax; Days to recurrence: 746 days (2.0 years).
- Days to follow up: 749 days (2.1 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B6-A0I8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 190 mg.
  Slide TCGA-B6-A0I8-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 1; Percent necrosis: 0; Percent stromal cells: 9; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-B6-A0I8-01A-01-BSA: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-B6-A0I8-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B6-A0I8-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: With tumor; Axillary staging method: No axillary staging; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Indeterminate (neither Pre or Postmenopausal); Micromet detection by IHC: No; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Biopsy, NOS; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Inner Quadrant; Anatomic organ subdivision: Right.
- Follow-up form: Tumor status: With tumor; New tumor event type: Locoregional Disease; New tumor event site other: Pectoral muscle; New tumor event surgery: Yes; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -2022.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 749 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 749 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 746 days.
